Somatic mutation profile of tumor specimen TCGA-14-1453-01A (aliquot TCGA-14-1453-01A-01W-0611-08) from TCGA case TCGA-14-1453, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.3 years (25,297 days).
Specimen TCGA-14-1453-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88b079b4-c109-4a55-a463-a28afbb5d414.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1453-10A (Blood Derived Normal), aliquot TCGA-14-1453-10A-01W-0612-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1d0ab2d-3330-4816-a710-be6d38d43be5

The open-access MAF lists 63 somatic variants for this specimen: 45 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 14, Nonsense Mutation 2, RNA 1, Intron 1, 3'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 33/85 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.1042C>G p.R348G | Missense Mutation (SNP) | VAF 176/579 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV63662151, COSV63662881; called by muse, mutect2, varscan2
- AP5S1 | c.152A>G p.K51R | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99853261; called by muse, mutect2
- APOB | c.7817C>T p.A2606V | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51929675; called by muse, mutect2, varscan2
- APOD | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 221/544 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as rs141030350; called by muse, mutect2, varscan2
- ATP10A | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147157402, COSV63513255; called by muse, mutect2, varscan2
- ATRN | c.3697G>T p.E1233* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | catalogued as COSV53525616; called by muse, mutect2, varscan2
- ATRX | c.5408G>A p.R1803H | Missense Mutation (SNP) | VAF 374/391 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64873488; called by muse, mutect2, varscan2
- ATXN2 | c.1532A>G p.Q511R (on ENST00000550104; = p.Q351R on NM_002973.4) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs746155300, COSV66482238; called by muse, mutect2, varscan2
- BPTF | c.8156G>A p.R2719Q | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV58834405; called by muse, mutect2, varscan2
- CACNA1E | c.6446C>G p.T2149S (on ENST00000367573 / NM_001205293.3; = p.T2106S on NM_000721.4) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as COSV100702518; called by muse, mutect2, varscan2
- CCR3 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as rs968670191, COSV62462409; called by muse, mutect2, varscan2
- CDS1 | c.665T>G p.L222R | Missense Mutation (SNP) | VAF 156/288 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55687318; called by muse, mutect2, varscan2
- CLEC6A | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1218968407, COSV65986944; called by muse, mutect2, varscan2
- DOCK5 | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 343/766 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV52398427; called by muse, mutect2, varscan2
- ELAVL4 | c.632A>T p.N211I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV63915255; called by muse, mutect2, varscan2
- FAM153B | c.701A>T p.Y234F (on ENST00000253490; = p.Y157F on NM_001265615.1) | Missense Mutation (SNP) | VAF 113/515 reads (22%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.251); catalogued as COSV53685864; called by muse, mutect2, varscan2
- FMNL1 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762893518, COSV58955993; called by muse, mutect2, varscan2
- GNA12 | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV51740924; called by muse, mutect2, varscan2
- HDAC9 | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 140/520 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67770898; called by muse, varscan2
- HJV | c.789G>C p.L263F (on ENST00000336751 / NM_213653.4; = p.L150F on NM_145277.5) | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60951597; called by muse, mutect2, varscan2
- IL17RD | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as rs980355864, COSV99577100; called by muse, mutect2, varscan2
- KARS1 | c.691T>C p.Y231H | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV100093839, COSV56691399; called by muse, mutect2, varscan2
- LMX1B | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1161738395, CM1210013, COSV62741108; called by muse, mutect2, varscan2
- MED28 | c.464A>C p.D155A | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV52845974; called by muse, varscan2
- MSL3 | c.789A>G p.I263M (on ENST00000312196 / NM_078629.4; = p.I97M on NM_006800.4) | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56492311; called by muse, mutect2, varscan2
- MYLPF | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237788851, COSV100363062; called by muse, mutect2, varscan2
- NALCN | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.194); catalogued as COSV51926007; called by muse, mutect2, varscan2
- NPHP4 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs571395593, COSV65394550; called by muse, mutect2, varscan2
- PIK3R1 | c.1282G>T p.V428L (on ENST00000521381 / NM_181523.3; = p.V158L on NM_181504.4) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV57127416; called by muse, mutect2, varscan2
- PKDREJ | c.6083G>A p.R2028Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1248665280, COSV53547728; called by muse, mutect2, varscan2
- PPP2R1A | c.1363+1G>C p.X455_splice | Splice Site (SNP) | VAF 19/303 reads (6%) | catalogued as COSV100436265, COSV59046210; called by muse, mutect2
- PTPRU | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs138353108; called by muse, mutect2, varscan2
- RASGEF1C | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376949886; called by muse, varscan2
- SCN11A | c.3605G>C p.G1202A | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56567940; called by muse, varscan2
- SSX1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 238/253 reads (94%) | SIFT tolerated (0.43); PolyPhen benign (0.103); catalogued as rs782680032, COSV65354964; called by muse, mutect2, varscan2
- SV2B | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 256/556 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as rs77109752; called by muse, mutect2, varscan2
- TCF7L2 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60503982; called by muse, mutect2, varscan2
- TGM5 | c.1741T>G p.Y581D (on ENST00000220420 / NM_201631.4; = p.Y499D on NM_004245.4) | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55009455; called by muse, mutect2, varscan2
- TTN | c.54319C>T p.R18107W (on ENST00000591111; = p.R10683W on NM_003319.4) | Missense Mutation (SNP) | VAF 238/257 reads (93%) | PolyPhen possibly damaging (0.857); catalogued as rs780429608, COSV59950017; called by muse, mutect2, varscan2
- UCMA | c.403C>G p.R135G | Missense Mutation (SNP) | VAF 55/62 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66321420, COSV66321647; called by muse, mutect2, varscan2
- XYLB | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200759971; called by muse, mutect2, varscan2
- ZNF208 | c.3371C>T p.T1124M | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.356); catalogued as rs202182044, COSV101237209, COSV68110370; called by muse, mutect2, varscan2
- ZNF215 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 44/69 reads (64%) | catalogued as rs372623841; called by muse, mutect2, varscan2
- ZNF699 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs763412003, COSV58025202; called by muse, mutect2, varscan2
- ATR | c.3519G>A p.K1173= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV100638206, COSV100638482, COSV63388119; called by muse, mutect2, varscan2
- CRNN | c.81G>A p.A27= | Silent (SNP) | VAF 116/283 reads (41%) | catalogued as rs768762957, COSV55121324; called by muse, mutect2, varscan2
- FLG | c.12057G>A p.A4019= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs370295034; called by muse, mutect2, varscan2
- HTR3B | c.741G>C p.L247= | Silent (SNP) | VAF 75/187 reads (40%) | catalogued as COSV52743577; called by muse, mutect2, varscan2
- MYH11 | c.1110G>A p.A370= | Silent (SNP) | VAF 136/398 reads (34%) | catalogued as rs746485704, COSV55547710; called by muse, varscan2
- OR8K3 | c.891A>G p.K297= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs1277282412, COSV57131068; called by muse, mutect2, varscan2
- PCDHA1 | c.1854G>A p.A618= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs543937372, COSV65374214; called by muse, mutect2, varscan2
- PLEKHG2 | c.405C>T p.G135= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs753502037, COSV52684442; called by muse, varscan2
- PPP6R2 | c.153G>A p.Q51= | Silent (SNP) | VAF 45/426 reads (11%) | catalogued as rs1295364827, COSV99324194; called by muse, mutect2, varscan2
- S100A2 | c.72G>A p.E24= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs752164817, COSV100905947, COSV100905958; called by muse, varscan2
- SCN1A | c.2331T>C p.C777= (on ENST00000303395 / NM_001202435.3; = p.C766= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/101 reads (53%) | catalogued as COSV57665242; called by muse, mutect2, varscan2
- TRIO | c.2481C>T p.R827= | Silent (SNP) | VAF 23/308 reads (7%) | catalogued as COSV100710332; called by muse, mutect2
- VPS50 | c.2787G>A p.T929= | Silent (SNP) | VAF 48/211 reads (23%) | catalogued as COSV59917216; called by muse, mutect2, varscan2
- XIRP2 | c.690A>C p.S230= (on ENST00000628543; = p.S405= on NM_152381.6) | Silent (SNP) | VAF 64/141 reads (45%) | catalogued as COSV54690663, COSV54696922; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846503 A>G | 5'Flank (SNP) | VAF 77/332 reads (23%) | called by muse, mutect2, varscan2
- SEPTIN4 | c.1606+31G>C | Intron (SNP) | VAF 100/102 reads (98%) | catalogued as COSV58727463; called by muse, mutect2, varscan2
- SNORD116-22 | n.61T>G | RNA (SNP) | VAF 203/433 reads (47%) | called by muse, mutect2, varscan2
- VMP1 | c.*1G>A | 3'UTR (SNP) | VAF 96/101 reads (95%) | catalogued as COSV51865907; called by muse, mutect2, varscan2
